TARGET case TARGET-15-SJMPAL043775 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/539547e0-c31a-4d06-82b4-16c9657c6934

Demographics
Sex at birth: male; Age at index: 1 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 1.9 years (699 days); Year of diagnosis: 2013; Days to last follow up: 838 days (2.3 years).

Follow-up (1 entry)
- Days to follow up: 838 days (2.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 838; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 41 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL043775-09A, TARGET-15-SJMPAL043775-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL043775-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 838
- Protocol: Singapore
- WBC at Diagnosis: 41
- Initial Therapy: ALL
- Karyotype: 46,XY,t(9;22)(q34;q11.2)[5]/47,idem,add(5)(q22),+der(22)t(9;22)[9]/46,XY[6]
- WHO ALAL Classification: Ph+
- WHO Dx: Ph+
